Somatic mutation profile of tumor specimen TARGET-15-SJMPAL044950-09A (aliquot TARGET-15-SJMPAL044950-09A-01D) from TARGET case TARGET-15-SJMPAL044950, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.1 years (41 days).
Specimen TARGET-15-SJMPAL044950-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e56aa95-07e1-4fab-9882-e3c893eb3acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL044950-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL044950-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02c50039-f3e2-49bf-ba03-0f0690bbf311

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as COSV62268046; called by muse, mutect2
- IL1RAPL2 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV61150635; called by muse, mutect2
- MARF1 | c.2614G>T p.A872S | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.275); catalogued as COSV60026074; called by muse, mutect2
- ANKRD33B | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2
- APLP1 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- CXXC4 | c.1007G>T p.C336F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGB1 | c.6963G>T p.L2321F | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.232); called by muse, mutect2
- RASSF5 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.194); called by muse, mutect2
- MUC5B | c.2058C>A p.G686= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
